CCDI case PBCLPF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0bfbef40-d3dc-4e13-9d76-e32bf0d82e70

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (564 days).

Biospecimens (3 samples)
- Sample 0DUNOB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUNP3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUNPZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
